Somatic mutation profile of tumor specimen MBCProject_0946_T1_WES (aliquot MBCProject_0946_T1_WES_1) from CMI case MBCProject_0946, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.9 years (16,407 days).
Specimen MBCProject_0946_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ba21c1e-0ffd-40c1-a709-45a85e85b40d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0946_SALIVA (Saliva), aliquot MBCProject_0946_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbdf5bf4-a9b0-4201-a363-8a889d695cef

The open-access MAF lists 48 somatic variants for this specimen: 26 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 15, Intron 3, 5'Flank 2, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 35/131 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI3 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.692); catalogued as rs1039159888; called by muse, mutect2, varscan2
- BCOR | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as rs373753191; called by muse, mutect2, varscan2
- CMTM6 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1400075364; called by muse, mutect2, varscan2
- DAPK1 | c.3163C>T p.R1055W | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs370890284; called by muse, mutect2, varscan2
- FADS3 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1459698997, COSV99605464; called by muse, mutect2, varscan2
- GRM3 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs377667772; called by muse, mutect2
- KEL | c.1675C>A p.P559T | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV62337250; called by muse, mutect2
- KIAA1522 | c.479G>A p.R160Q (on ENST00000373480 / NM_001198972.2; = p.R219Q on NM_020888.3) | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372939895, COSV53867014; called by muse, mutect2, varscan2
- KRT27 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1323211995, COSV56973708; called by muse, mutect2
- POGLUT1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs369098373; called by muse, mutect2, varscan2
- RB1CC1 | c.337C>G p.H113D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs963227983; called by muse, varscan2
- RPGR | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.267); catalogued as COSV100140664; called by muse, mutect2, varscan2
- SLC22A12 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs1384341957, COSV60572317; called by muse, mutect2, varscan2
- ATP2B4 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- C11orf87 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC80 | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- COQ8A | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 81/524 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KCNIP4 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LCE1C | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LRRC75A | c.577G>T p.V193L (on ENST00000470794 / NM_001113567.3; = p.G154V on NM_207387.4) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAP2K4 | c.565del p.Y189Tfs*8 | Frame Shift Del (DEL) | VAF 41/115 reads (36%) | called by mutect2, pindel, varscan2
- NF1 | c.1740_1752del p.I581* | Frame Shift Del (DEL) | VAF 34/192 reads (18%) | called by pindel, varscan2
- OR8K3 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- RRP1B | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SMG5 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACR | c.612C>T p.I204= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as rs372838594; called by muse, mutect2, varscan2
- CCDC127 | c.594C>T p.P198= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs372308365, COSV57258177; called by muse, mutect2, varscan2
- CIC | c.1824C>T p.G608= | Silent (SNP) | VAF 57/186 reads (31%) | called by muse, mutect2, varscan2
- DCTN4 | c.25C>A p.R9= | Silent (SNP) | VAF 78/226 reads (35%) | catalogued as rs1271434084; called by muse, mutect2, varscan2
- LRRC7 | c.3477C>T p.S1159= (on ENST00000651989 / NM_001370785.2; = p.S1126= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs772773571, COSV50443897, COSV99226586; called by muse, mutect2, varscan2
- MKRN3 | c.1212G>A p.A404= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as rs199638466, COSV58812657; called by muse, varscan2
- OR2D2 | c.462G>T p.L154= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100203765; called by muse, mutect2, varscan2
- OR52E2 | c.633C>T p.D211= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- PCDHA11 | c.2193C>T p.C731= | Silent (SNP) | VAF 19/359 reads (5%) | called by muse, mutect2
- PCDHA3 | c.1443C>T p.D481= | Silent (SNP) | VAF 66/1448 reads (5%) | catalogued as rs782385485, COSV63538919; called by muse, mutect2
- PCDHA9 | c.1443C>T p.D481= | Silent (SNP) | VAF 324/1178 reads (28%) | catalogued as COSV65329757; called by muse, varscan2
- PRKAR1A | c.21C>T p.A7= | Silent (SNP) | VAF 71/327 reads (22%) | catalogued as rs753565093, COSV100675239, COSV62235147; called by muse, mutect2, varscan2
- RRP15 | c.813C>T p.D271= | Silent (SNP) | VAF 19/223 reads (9%) | catalogued as rs1164536183, COSV100860756; called by muse, mutect2
- TRPM8 | c.513C>T p.I171= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs151205278, COSV61221999; called by muse, mutect2, varscan2
- UBR5 | c.1584C>T p.I528= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV55280095; called by muse, mutect2, varscan2
- ETFA | c.664+732T>C | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- MIR450A1 | n.43C>G | RNA (SNP) | VAF 6/58 reads (10%) | catalogued as rs1298433316; called by mutect2, varscan2
- OBSCN | c.4585+2747C>G | Intron (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- UACA | c.78+9258A>G | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as rs1179514522; called by mutect2, varscan2
- ZNF131 | chr5:43120013 A>G | 5'Flank (SNP) | VAF 7/75 reads (9%) | catalogued as rs1163968436; called by muse, mutect2
- ZNF812P | n.1536C>A | RNA (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ZSCAN16 | chr6:28123185 T>C | 5'Flank (SNP) | VAF 8/160 reads (5%) | catalogued as rs1251369244; called by muse, mutect2
